Somatic mutation profile of tumor specimen TARGET-30-PASVKL-09A (aliquot TARGET-30-PASVKL-09A-01D) from TARGET case TARGET-30-PASVKL, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 3.6 years (1,300 days).
Specimen TARGET-30-PASVKL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 431bc3c9-1fe4-4e6d-b032-8bd9a0e96aab.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASVKL-10A (Blood Derived Normal), aliquot TARGET-30-PASVKL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65afe80f-21f1-49bd-8b69-bdf1935686d6

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOXA5 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56074887; called by muse, mutect2
- ASB5 | c.*1591G>T | 3'UTR (SNP) | VAF 94/200 reads (47%) | catalogued as COSV56671086; called by muse, mutect2, varscan2
- CACNA1A | c.4879-48G>A | Intron (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
